Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A0JG, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A0JG-01A (Primary Tumor).

[page 1 of 4]
Clinical Diagnosis & History:

year old female with 2.7 cm right breast cancer, lower outer quadrant and
FNA (+) metastatic right lymph node.

Specimens Submitted:

- 1: SP: Right breast and axillary contents levels one and two with tags
attached
2: SP: Subscapular nodes, right axilla level one

DIAGNOSIS:

1. BREAST, RIGHT; MASTECTOMY AND AXILLARY DISSECTION:
- INVASIVE DUCTAL CARCINOMA, MIXED MUCINOUS & NOS TYPE AND WITH SOLID-PAPILLARY FEATURES, HISTOLOGIC GRADE III/III (SLIGHT OR NO TUBULE FORMATION), NUCLEAR GRADE II/III (MODERATE VARIATION IN SIZE AND SHAPE), MEASURING 2.3 CM IN LARGEST DIMENSION MICROSCOPICALLY.
- (DCIS) IS ALSO IDENTIFIED, SOLID AND CRIBRIFORM TYPES WITH INTERMEDIATE NUCLEAR GRADE AND MINIMAL NECROSIS.
- LOBULAR INVOLVEMENT BY DCIS IS PRESENT.
- THE DCIS CONSTITUTES LESS THAN OR EQUAL TO 25% OF THE TOTAL TUMOR MASS, AND IS PRESENT ADMIXED WITH AND AWAY FROM THE INVASIVE COMPONENT.
- THE INVASIVE CARCINOMA IS LOCATED IN THE LOWER OUTER QUADRANT
- THE DCIS IS LOCATED IN THE LOWER OUTER QUADRANT AND LOWER INNER QUADRANT
- NO INVOLVEMENT OF THE NIPPLE BY EITHER IN SITU OR INVASIVE CARCINOMA IS IDENTIFIED.
- CALCIFICATIONS ARE PRESENT IN BENIGN BREAST PARENCHYMA.
- VASCULAR INVASION IS PRESENT.
- INVASIVE CARCINOMA IS CLOSE (LESS THAN OR EQUAL TO 1 MM) TO THE FOLLOWING SURGICAL MARGIN(S): BLUE INKED MARGIN (ANTERIOR).
- NO SKIN INVOLVEMENT BY CARCINOMA IS IDENTIFIED.
- THE NON-NEOPLASTIC BREAST TISSUE SHOWS BIOPSY SITE CHANGES AND PROLIFERATIVE FIBROCYSTIC CHANGES INCLUDING INTRADUCTAL PAPILLOMA.
- LEVEL 1: METASTATIC ADENOCARCINOMA TO FOUR OUT OF TEN LYMPH NODES (4/10)
- THE LARGEST METASTATIC FOCUS MEASURES 2.5 CM
THERE IS EXTRANODAL EXTENSION OF CARCINOMA, FOCAL.
- LEVEL 2 : THREE BENIGN LYMPH NODES (0/3)

1

** Continued on next page **

1CD-0-3

carcinoma, infiltrating duct and mucinous
Site: breast, nos c50.9 lw 8523/3
10/22/11

	Yes	No
Criteria		

[page 2 of 4]
Page 2 of 4
- IMMUNOHISTOCHEMICAL STAIN WAS PERFORMED ON FORMALIN-FIXED TISSUE WITH THE
FOLLOWING RESULTS FOR INVASIVE CARCINOMA (BLOCK 1T6):

HER2

NEGATIVE (0 / 1+)

5% OF INVASIVE TUMOR CELLS EXHIBIT COMPLETE MEMBRANOUS STAINING;
UNIFORMITY OF STAINING: ABSENT
HOMOGENEOUS, DARK CIRCUMFERENTIAL PATTERN: ABSENT

Comment: Controls are satisfactory.

s PATHWAY anti-HER-2/neu is an FDA-approved rabbit monoclonal primary antibody (clone 4B5) directed against the internal domain of the c-erbB-2 oncoprotein (HER2) for immunohistochemical detection of HER2 protein overexpression in breast cancer tissue routinely processed for histologic evaluation. The HER2 test results are reported in accordance with the ASCO/CAP guideline recommendations for HER2 testing in breast cancer (J Clin Oncol 2007; 25(1):118-145). The ER and PR rabbit monoclonal antibodies are also FDA approved.

2. LYMPH NODES, RIGHT AXILLA LEVEL ONE, SUBCAPSULAR:
- SIX BENIGN LYMPH NODES (0/6).

Some of the immunohistochemistry and tests were developed and their performance characteristics were determined by They have not been cleared or approved by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA '88) as qualified to perform high complexity clinical laboratory testing.

2

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1).The specimen is received fresh labeled, "right breast and axillary contents levels one and two with tags attached" and consists of a breast measuring 19 x 18 x 3 cm with overlying skin ellipse measuring 11 x 3 cm. Situated centrally on the skin surface is an everted nipple measuring 1 x 1 x 0.6 cm and areola measuring 3 x 3 cm. A suture demarcates the axillary contents which measures 11 x 7 x 3 cm. Two tags are present, designating levels one and two. The posterior surface of the breast is inked black, the anterior blue and the axillary aspect is inked yellow. The specimen is serially sectioned to reveal a 2.5 cm diameter mass in the lower outer

** Continued on next page **

[page 3 of 4]
quadrant and 1 cm from the deep margin. A clip is identified in the mass. The remaining breast tissue shows nodular fibroadipose tissue. The axillary tissue is dissected to reveal multiple lymph nodes, ranging in size from 0.5 cm to 2.5 cm. Representative sections are submitted. All dissected lymph nodes are entirely submitted.

Summary of sections:

N - nipple
NB - nipple base
D - deep margin
T - tumor
UIQ - upper inner quadrant
LIQ - lower inner quadrant
UOQ - upper outer quadrant
LOQ - lower outer quadrant
L1 lymph nodes, level 1
L2 lymph nodes level 2

2). The specimen is received in formalin, labeled "subscapular nodes right axilla level one" and consists of pink tan firm lymph nodes ranging from 0.8 to up 2 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN -- lymph nodes
BLN-- bisected lymph nodes

Summary of Sections:

Part 1: SP: Right breast and axillary contents levels one and two with tags attached

Block	Sect. Site	PCs
1	D	1
6	L1	6
1	L2	2
1	LIQ	1
1	LOQ	1
2	N	1
1	NB	2
3	T	1
1	UIQ	3
1	UOQ	1
		1

Part 2: SP: Subscapular nodes, right axilla level one

Block	Sect. Site	PCs
2	BLN	2
1	LN	1

** Continued on next page **

[page 4 of 4]
4

** End of Report **

Source: NCI Genomic Data Commons file 16e1ae3e-5438-48aa-9ce6-7d57fae5b5fe (TCGA-AO-A0JG.3671D46F-6D69-42DA-9830-24F67EB8B0B6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).